Somatic mutation profile of tumor specimen HTMCP-03-06-02366-01A (aliquot HTMCP-03-06-02366-01A-01D-9392) from CGCI case HTMCP-03-06-02366, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89a49d15-519d-4974-9f13-7260406a9049.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02366-10A (Blood Derived Normal), aliquot HTMCP-03-06-02366-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b78ecb87-d635-4dae-a0db-ccb92740f0a5

The open-access MAF lists 59 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 4, 5'UTR 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AJM1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs1399574299; called by muse, mutect2, varscan2
- CNTNAP4 | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV56683207; called by muse, mutect2
- CR1 | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750014956, COSV65457444; called by muse, mutect2
- DLG5 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64950317; called by muse, mutect2, varscan2
- DNMBP | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs767195437; called by muse, mutect2, varscan2
- DSCAM | c.5461G>A p.A1821T | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1208234992, COSV68032312; called by muse, mutect2, varscan2
- EPS8L2 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV59346785, COSV59348887; called by muse, mutect2, varscan2
- GOLGA1 | c.1978G>A p.D660N | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs757460981; called by muse, mutect2, varscan2
- HMCN2 | c.8282G>A p.R2761Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs1346553882; called by muse, mutect2
- KCNA5 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.109); catalogued as rs1176110728; called by muse, varscan2
- KMT2C | c.6851C>G p.S2284* | Nonsense Mutation (SNP) | VAF 31/138 reads (22%) | catalogued as COSV51297256; called by muse, mutect2, varscan2
- LAMA3 | c.5150G>A p.R1717H (on ENST00000313654 / NM_198129.4; = p.R108H on NM_000227.6) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs754903702, COSV52535546; called by muse, mutect2, varscan2
- NKAP | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57630392; called by muse, mutect2, varscan2
- PCLO | c.8008C>T p.L2670F | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61623490; called by muse, mutect2, varscan2
- PCLO | c.5861A>T p.D1954V | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423656700; called by muse, mutect2, varscan2
- REST | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1452216654; called by muse, mutect2, varscan2
- SLC38A9 | c.527-4C>T | Splice Region (SNP) | VAF 15/98 reads (15%) | catalogued as rs765192231; called by muse, mutect2, varscan2
- SMTN | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs370156932; called by muse, mutect2, varscan2
- SULF1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769577350, COSV52673496, COSV52687237; called by muse, mutect2, varscan2
- SYNE1 | c.10918C>T p.Q3640* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | catalogued as COSV99570912; called by muse, mutect2, varscan2
- ZSWIM8 | c.3398G>A p.R1133Q (on ENST00000605216 / NM_001242487.2; = p.R1138Q on NM_015037.3) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs1351085919, COSV55212930; called by muse, mutect2
- CRYBG3 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 31/373 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2
- CXorf56 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- DICER1 | c.3601C>T p.Q1201* | Nonsense Mutation (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- EML6 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FANCD2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- GRIN2A | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGSF22 | c.2498G>T p.G833V (on ENST00000319338; = p.G934V on NM_173588.4) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- LRRC7 | c.2999A>G p.N1000S (on ENST00000651989 / NM_001370785.2; = p.N967S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- POLK | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RNF213 | c.7886C>T p.T2629I | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- RPS6KA6 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC4A10 | c.2530C>A p.H844N (on ENST00000446997 / NM_001354461.2; = p.H814N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.576); called by muse, mutect2, varscan2
- STARD9 | c.10676G>A p.R3559Q | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYCP2 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.143); called by muse, mutect2
- THOC2 | c.3730G>A p.A1244T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPM2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- TPTE2 | c.812C>T p.A271V (on ENST00000400230 / NM_199254.2; = p.A194V on NM_130785.3) | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- VPS8 | c.2710G>A p.E904K (on ENST00000625842 / NM_001349294.1; = p.E902K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- VWA5B1 | c.1664C>G p.S555* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- DOCK7 | c.97C>T p.L33= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- EMX2 | c.300C>G p.P100= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- EVC2 | c.3810G>A p.E1270= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs1008781056, COSV100186334; called by muse, mutect2, varscan2
- FBXO34 | c.249G>A p.L83= | Silent (SNP) | VAF 28/339 reads (8%) | called by muse, mutect2
- GRIN2A | c.3876C>T p.Y1292= | Silent (SNP) | VAF 48/242 reads (20%) | catalogued as rs749688882, COSV58056734; called by muse, mutect2, varscan2
- INPP5D | c.483C>T p.S161= (on ENST00000445964 / NM_001017915.3; = p.S160= on NM_005541.5) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs376568019; called by muse, mutect2, varscan2
- MROH2B | c.1893T>C p.F631= | Silent (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- NPHP4 | c.2595G>T p.T865= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV65398049; called by muse, mutect2, varscan2
- PABPC3 | c.1140C>T p.N380= | Silent (SNP) | VAF 25/206 reads (12%) | catalogued as rs759948013, COSV55802540; called by muse, varscan2
- PCDH15 | c.4887G>A p.E1629= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV64701383; called by muse, mutect2
- PCDHGA12 | c.1290G>A p.P430= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as rs373867677; called by muse, mutect2, varscan2
- PLXNA4 | c.3042G>T p.V1014= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- RANBP6 | c.2187G>A p.V729= | Silent (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- ZNF750 | c.300G>A p.S100= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs35785432; called by muse, mutect2, varscan2
- ABI3BP | c.-17G>A | 5'UTR (SNP) | VAF 12/29 reads (41%) | catalogued as rs763961798; called by muse, mutect2, varscan2
- FAM81B | c.294-7682G>A | Intron (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- NADK | c.-4G>A | 5'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- TMIGD3 | c.215-625T>C | Intron (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
